Somatic mutation profile of tumor specimen TARGET-20-PASADG-04A (aliquot TARGET-20-PASADG-04A-01D) from TARGET case TARGET-20-PASADG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.1 years (4,424 days).
Specimen TARGET-20-PASADG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2be3a5f-27af-4e61-ab40-9155500e9075.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASADG-14A (Bone Marrow Normal), aliquot TARGET-20-PASADG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0a6d656-861e-4c0a-b1e2-00c30503a0cb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 31/214 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- RELN | c.4241G>A p.S1414N | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
